Gene-level copy-number profile of tumor specimen TARGET-40-PANSEN-01A from TARGET case TARGET-40-PANSEN, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 14.3 years (5,234 days).
Specimen TARGET-40-PANSEN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.47e3c642-aa83-5014-8675-6561a6f37632.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PANSEN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 401 have no estimate.
https://portal.gdc.cancer.gov/files/4430f88b-3538-4ec3-a5d7-b2db4b310051

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 1,417; copy number 2: 23,490; copy number 3: 12,255; copy number 4: 11,796; copy number 5: 8,570; copy number 6: 760; copy number 7: 1,375; copy number 8: 231; copy number 9: 72; copy number 10: 83; copy number 11: 157; copy number 12: 4.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:79,966,805–79,989,630, 2 genes: AP001541.1, AP001284.1.
- chr11:80,527,960–80,528,066, 1 gene: RNU6-544P.
- chr17:7,591,230–7,833,744, 9 genes (within-gene range 0–5): FXR2, SHBG, SAT2, ATP1B2, TP53, WRAP53, EFNB3, DNAH2, RPL29P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11,232 genes in 47 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,555,001–13,825,079, 6 genes, copy number 5: BRWD1P1, PDPN, RNA5SP41, AL359771.1, AL359771.2, PRDM2.
- chr1:17,277,889–17,277,975, 1 gene, copy number 8: MIR3972.
- chr1:47,483,698–99,244,794, 849 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:102,763,322–190,801,658, 1,780 genes, copy number 5 (within-gene range 5–7) (broad region; genes not listed).
- chr1:193,473,224–194,198,708, 1 gene, copy number 5 (within-gene range 4–6): AL136456.1.
- chr1:193,756,815–195,763,501, 7 genes, copy number 5: RPL23AP22, EEF1A1P14, AL513348.1, RNU6-983P, AL353072.1, AL353072.2, AL353709.1.
- chr2:52,071,355–52,298,096, 2 genes, copy number 6: ZNF863P, Y_RNA.
- chr2:88,811,186–88,861,563, 2 genes, copy number 5 (within-gene range 3–5): MALLP2, AC244205.1.
- chr2:88,857,161–128,067,901, 766 genes, copy number 5 (broad region; genes not listed).
- chr3:1,595,777–3,627,296, 17 genes, copy number 5: RPL23AP38, RPL23AP39, RPL21P17, AC018814.1, RN7SKP144, CNTN4, CNTN4-AS2, AC087427.1, HINT2P1, DNAJC19P4, CNTN4-AS1, IL5RA, AC024060.1, TRNT1, CRBN, AC024060.2, AC034195.1.
- chr3:6,892,632–7,790,482, 4 genes, copy number 5: GRM7-AS2, AC066585.1, GRM7-AS1, AC077690.1.
- chr3:27,369,568–28,059,268, 15 genes, copy number 6 (within-gene range 2–6): AC099535.2, SLC4A7, RPS20P15, AC099535.1, RNU1-96P, AC137675.1, Y_RNA, AC098614.1, AC098614.2, KIAA1143P2, LINC02084, EOMES, LINC01980, LINC01981, LINC01967.
- chr3:90,030,284–90,261,708, 4 genes, copy number 6: U3, RNU6-712P, PROS2P, HSPE1P19.
- chr4:95,644,952–95,868,764, 3 genes, copy number 5: RPL30P6, PDHA2, RNU6-1059P.
- chr5:50,603,229–62,628,582, 190 genes, copy number 5–9 (within-gene range 2–9) (broad region; genes not listed).
- chr5:62,575,951–71,259,238, 135 genes, copy number 6 (broad region; genes not listed).
- chr5:71,372,676–71,385,993, 2 genes, copy number 6 (within-gene range 2–6): AC145141.2, PMCHL2.
- chr7:70,837,738–79,453,667, 190 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:78,347,142–113,494,870, 593 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:131,110,096–148,420,998, 380 genes, copy number 5 (within-gene range 2–8) (broad region; genes not listed).
- chr8:46,028,804–145,006,046, 1,532 genes, copy number 5–7 (broad region; genes not listed).
- chr9:60,914,407–109,324,796, 836 genes, copy number 5 (broad region; genes not listed).
- chr10:45,815,428–47,730,436, 57 genes, copy number 6: FAM25E, AGAP4, PARGP1, RNA5SP310, RPL35AP23, TIMM23, SNORA74C-1, NCOA4, MSMB, RPL23AP61, AGAP7P, ANTXRLP1, ANTXRL, AGAP14P, FAM25BP, AC244230.1, ANXA8L1, AC244230.2, LINC00842, HNRNPA1P33, NPY4R, GPRIN2, SYT15, AL356056.2, AL356056.1, SHLD2P1, LINC02637, RHEBP1, RN7SL248P, FAM245B, CTSLP3, GLUD1P2, AL731733.1, BMS1P1, RNA5SP311, AGAP13P, FRMPD2B, PTPN20, GDF10, GDF2, RBP3, ZNF488, ANXA8, AL591684.3, FAM25G, AL591684.1, AGAP9, AL591684.2, RNA5SP312, BMS1P2, BX547991.1, DUSP8P1, CTSLP2, LINC02675, SHLD2P3, RN7SL453P, RHEBP2.
- chr12:34,149,839–39,170,880, 27 genes, copy number 6–7: AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1, ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1.
- chr12:45,729,706–47,420,192, 32 genes, copy number 5 (within-gene range 3–5): ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1, AMIGO2, PCED1B, IFITM3P6, MIR4698, PCED1B-AS1, AC008083.2, AC008083.3, AC008083.4, PPIAP45, AC008083.1, LINC02416, MIR4494, LINC02156.
- chr12:79,934,901–80,937,925, 17 genes, copy number 5: PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P, OTOGL, AC078817.1, RN7SKP261, PTPRQ, AKIRIN1P1, AC074031.1, MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618.
- chr12:85,781,892–85,782,444, 1 gene, copy number 6: AC137768.1.
- chr14:21,016,763–99,535,044, 1,615 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr15:88,797,413–101,933,350, 332 genes, copy number 5–10 (broad region; genes not listed).
- chr16:68,358,327–68,477,570, 6 genes, copy number 6: SMPD3, AC099521.2, AC099521.3, AC099521.1, Y_RNA, RPL35AP33.
- chr17:2,755,705–7,584,086, 243 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:7,839,904–22,706,703, 559 genes, copy number 5–11 (broad region; genes not listed).
- chr18:39,622,123–40,247,367, 11 genes, copy number 5: MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45, AC068688.1.
- chr19:27,983,032–33,521,791, 115 genes, copy number 6–12 (within-gene range 3–12) (broad region; genes not listed).
- chr21:12,999,676–13,793,141, 28 genes, copy number 6: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P, LINC01674, SNX19P1, OR4K11P, OR4K12P, POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2, FEM1AP1, AL050303.1, TERF1P1, FAM207CP.
- chr21:14,818,843–15,014,430, 2 genes, copy number 8 (within-gene range 4–8): AF127577.4, LINC02246.
- chr21:14,918,534–19,900,043, 73 genes, copy number 6–12 (broad region; genes not listed).
- chr21:23,857,081–36,295,702, 259 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr22:16,405,330–22,923,034, 430 genes, copy number 5 (broad region; genes not listed).
- chr22:24,429,206–27,573,573, 103 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,269. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
